Somatic mutation profile of tumor specimen 0DQ2NB from CCDI case PBCEEC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 10.0 years (3,663 days).
Specimen 0DQ2NB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3826a46a-c4cd-4d74-b1fd-37bf5a5d1e19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ2OW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f98bc363-e8ff-48df-9487-2c70673589b1

The open-access MAF lists 57 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 13, Intron 7, 3'UTR 2, Splice Region 2, Nonsense Mutation 2, Splice Site 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6AP2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 223/518 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs751433380; ClinVar: uncertain significance; called by muse, varscan2
- DPY19L2 | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 70/980 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV100116520; called by muse, varscan2
- GOLGA8A | c.1771C>T p.P591S (on ENST00000432566; = p.P563S on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/439 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs776626062; called by muse, varscan2
- HK2 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 56/340 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.616); catalogued as rs772185128, COSV51873179; called by muse, varscan2
- KCNH2 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs199473668, CM097526; ClinVar: uncertain significance; called by muse, varscan2
- KTN1 | c.3948G>A p.T1316= (on ENST00000395314 / NM_001271014.2; = p.T1259= on NM_004986.4) | Splice Region (SNP) | VAF 97/558 reads (17%) | catalogued as rs752354703, COSV58539850; called by muse, varscan2
- PAX9 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 86/519 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.382); catalogued as rs775496217; called by muse, varscan2
- RGS7BP | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 160/558 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.656); catalogued as rs1388089169, COSV61834366; called by muse, varscan2
- TBK1 | c.80G>T p.R27I | Missense Mutation (SNP) | VAF 106/862 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1425135718; called by muse, varscan2
- ZFP42 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 94/426 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750318279, COSV58817208, COSV58818962; called by muse, varscan2
- ZNF425 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as rs766863560, COSV100955394; called by muse, varscan2
- ABCA6 | c.4654G>C p.D1552H | Missense Mutation (SNP) | VAF 130/645 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ACTL6B | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.424); called by muse, varscan2
- ADGRE2 | c.2164T>C p.S722P | Missense Mutation (SNP) | VAF 67/372 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, varscan2
- BRWD3 | c.4240A>G p.S1414G | Missense Mutation (SNP) | VAF 81/504 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); called by muse, varscan2
- CLTRN | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 114/628 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.835); called by muse, varscan2
- DOCK5 | c.2242A>C p.S748R | Missense Mutation (SNP) | VAF 270/844 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, varscan2
- HSP90AA1 | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 51/450 reads (11%) | called by muse, varscan2
- IBSP | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 85/488 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, varscan2
- IFIH1 | c.1096-2A>G p.X366_splice | Splice Site (SNP) | VAF 120/690 reads (17%) | called by muse, varscan2
- MUC16 | c.23260C>G p.L7754V | Missense Mutation (SNP) | VAF 118/330 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, varscan2
- MYO9A | c.5731G>C p.A1911P | Missense Mutation (SNP) | VAF 117/644 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); called by muse, varscan2
- PCDHGA6 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 73/408 reads (18%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.031); called by muse, varscan2
- PPFIBP1 | c.1702C>T p.Q568* (on ENST00000318304 / NM_177444.3; = p.Q562* on NM_003622.4) | Nonsense Mutation (SNP) | VAF 121/778 reads (16%) | called by muse, varscan2
- PRSS22 | c.843C>A p.H281Q | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, varscan2
- SACS | c.12758A>G p.Q4253R | Missense Mutation (SNP) | VAF 72/351 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, varscan2
- SLC2A3 | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 86/778 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- SLF1 | c.2420-4G>T | Splice Region (SNP) | VAF 82/444 reads (18%) | called by muse, varscan2
- SSPN | c.77A>T p.D26V | Missense Mutation (SNP) | VAF 63/450 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.401); called by muse, varscan2
- TMEM200C | c.644C>G p.A215G | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); called by muse, varscan2
- WNT9A | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.739); called by muse, varscan2
- ZBTB10 | c.547A>T p.S183C | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); called by muse, varscan2
- ZNF197 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 114/473 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, varscan2
- C2orf72 | c.771G>A p.E257= | Silent (SNP) | VAF 84/402 reads (21%) | called by muse, varscan2
- CAD | c.1875C>T p.G625= | Silent (SNP) | VAF 74/659 reads (11%) | called by muse, varscan2
- DLGAP1 | c.1863C>T p.N621= | Silent (SNP) | VAF 77/423 reads (18%) | called by muse, varscan2
- FAHD2B | c.375C>G p.P125= | Silent (SNP) | VAF 54/514 reads (11%) | called by muse, varscan2
- HSF4 | c.453G>A p.E151= | Silent (SNP) | VAF 53/257 reads (21%) | called by muse, varscan2
- MTMR1 | c.111C>T p.A37= | Silent (SNP) | VAF 47/184 reads (26%) | catalogued as rs1450603310; called by muse, varscan2
- PPFIA2 | c.336C>T p.A112= | Silent (SNP) | VAF 113/982 reads (12%) | called by muse, varscan2
- PPP1R2C | c.463A>C p.R155= | Silent (SNP) | VAF 120/517 reads (23%) | called by muse, varscan2
- PTPN5 | c.192G>A p.P64= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as rs756875806; called by muse, varscan2
- RIN2 | c.225G>C p.S75= (on ENST00000255006 / NM_001242581.1; = p.S26= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/800 reads (13%) | catalogued as rs377404678; called by muse, varscan2
- SPTBN2 | c.1893G>A p.A631= | Silent (SNP) | VAF 50/231 reads (22%) | catalogued as rs778170822; called by muse, varscan2
- TERT | c.255G>A p.L85= | Silent (SNP) | VAF 24/216 reads (11%) | catalogued as COSV57244053; called by muse, varscan2
- TREML1 | c.447C>G p.A149= | Silent (SNP) | VAF 143/484 reads (30%) | called by muse, varscan2
- ACSS3 | c.921+68C>A | Intron (SNP) | VAF 34/220 reads (15%) | called by muse, varscan2
- ANXA5 | c.903+92G>T | Intron (SNP) | VAF 66/274 reads (24%) | called by muse, varscan2
- CD22 | c.1508-83G>A | Intron (SNP) | VAF 18/95 reads (19%) | catalogued as rs1032426085; called by muse, varscan2
- EMB | c.*95T>C | 3'UTR (SNP) | VAF 52/328 reads (16%) | called by muse, varscan2
- GRK2 | c.1654+11C>A | Intron (SNP) | VAF 44/200 reads (22%) | called by muse, varscan2
- KCNH7 | c.-72C>T | 5'UTR (SNP) | VAF 30/152 reads (20%) | called by muse, varscan2
- KEL | c.3+42G>T | Intron (SNP) | VAF 53/270 reads (20%) | called by muse, varscan2
- TBX2 | chr17:61412006 C>A | 3'Flank (SNP) | VAF 58/243 reads (24%) | called by muse, varscan2
- TMEM237 | c.274+262A>G | Intron (SNP) | VAF 56/508 reads (11%) | catalogued as rs1243696658; called by muse, varscan2
- WDR26 | c.928-53T>C | Intron (SNP) | VAF 26/178 reads (15%) | called by muse, varscan2
- ZNF740 | c.*5088C>A | 3'UTR (SNP) | VAF 42/360 reads (12%) | called by muse, varscan2
